CPTAC case C3L-00977 — Other and ill-defined sites in lip, oral cavity and pharynx — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b18f1b80-72f1-465c-816b-65e06d2b1fa6

Demographics
Sex at birth: male; Race: white; Year of birth: 1960; Vital status: Dead; Days to death: 1,537 days (4.2 years); Year of death: 2021; Cause of death: Cancer Related; Country of birth: Russia.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Site of resection or biopsy: Overlapping lesion of lip, oral cavity and pharynx; Age at diagnosis: 56.5 years (20,653 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G1; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,537 days (4.2 years); Progression or recurrence: no; Days to last follow up: 1,537 days (4.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 1.2 cm (a second GDC size field records 3 cm); Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 11; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (5 entries)
- Days to follow up: 377 days (1.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 772 days (2.1 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,112 days (3.0 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 853 days (2.3 years); Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,112 days (3.0 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,537 days (4.2 years); Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 110 kg; Height: 182 cm; BMI: 33.21; Comorbidities: Pancreatitis; Pancreatitis onset year: 2013.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Cigarettes per day: 20; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00977-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 33 days; Initial weight: 200 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00977-22: Section location: Oral Cavity; Percent tumor nuclei: 80; Percent necrosis: 3.
- Sample C3L-00977-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 33 days; Initial weight: 320 mg; Time between excision and freezing: 17 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00977-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 33 days; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00977-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 30 days; Method of sample procurement: Blood Draw.
